Somatic mutation profile of tumor specimen TARGET-10-PARFFC-03A (aliquot TARGET-10-PARFFC-03A-01D) from TARGET case TARGET-10-PARFFC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (794 days).
Specimen TARGET-10-PARFFC-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a701f983-7e14-44e8-b067-bf8925c09612.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFFC-14A (Bone Marrow Normal), aliquot TARGET-10-PARFFC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aba8b955-2bb1-4832-9d75-d145d50d3750

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, RNA 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HDAC7 | c.1709G>A p.R570Q (on ENST00000427332; = p.R609Q on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs751541720; called by muse, mutect2, varscan2
- XBP1 | c.454-2A>G p.X152_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV53274455; called by muse, varscan2
- FSIP2 | c.20165C>T p.T6722I | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HMCN2 | c.10802C>T p.P3601L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- IGKV2D-24 | chr2:90005619 CACAATTTCCTCACA>TAAG | Missense Mutation (DEL) | VAF 34/133 reads (26%) | called by pindel, varscan2*
- HSPA7 | n.182C>T | RNA (SNP) | VAF 10/59 reads (17%) | called by mutect2, varscan2
- SYTL2 | c.1459+1610C>T | Intron (SNP) | VAF 22/96 reads (23%) | catalogued as rs570172257; called by muse, mutect2, varscan2
